Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A553, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A553-01A (Primary Tumor).

Gross Description: There is a skin flap with black node up to 5.5x1.5 cm in size. There is a perifocal black spot up to 6 cm in its diameter.

Microscopic Description: Malignant melanoma of the skin with superficial ulceration. Breslow's tumor thickness is 10 mm. In the second skin fragment there is superficial melanoma of the malignant lentigo type.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.5 x 0 x 5.5 cm

Tumor features: Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Features: Pigmented, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments: Breslow's tumor thickness is 10 mm.

ICD-0-3

Melanoma, NOS 8720/3

Site: SKIN, trunk C44.5

lw
11/20/12

Histologic Discrepancy		☒
Discrepancy Primary Tumor		☒
Reviewed by (signature)	Date (signature) 11/19/12	

Source: NCI Genomic Data Commons file 0efddfe8-ba5b-4e44-9028-3a2a8e85619b (TCGA-EB-A553.4AD7A32C-248E-4BF1-99B3-505367A18DDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).